TARGET case TARGET-20-PARZHT — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c5e8fea3-8864-57c9-8631-251c85bd0532

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 9 years; Vital status: Alive.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; ICD-10 code: C92.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 9.6 years (3,498 days); Year of diagnosis: 2008; Days to last follow up: 2,584 days (7.1 years).
   Treatment given: Protocol identifier: AAML0531.
   Treatment given: Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Course number: 1; Timepoint category: End of Treatment Course.
   Treatment given: Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Course number: 2; Timepoint category: End of Treatment Course.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Gemtuzumab Ozogamicin.
   Recorded as not given: Stem Cell Transplantation, NOS, first complete response.

Follow-up (1 entry)
- Days to follow up: 2,584 days (7.1 years); Event-free: no event (relapse, second malignancy or death) recorded through day 2,584; Year of follow up: 2015.

Molecular and laboratory tests (laboratory values grouped by visit day)
- CEBPA mutation, nos: Negative.
- FLT3 internal tandem duplication: Negative.
- KIT mutation, nos: Negative; Exon: 17.
- KIT mutation, nos: Negative; Exon: 8.
- KMT2A translocation: Negative.
- Monosomy 5: Negative.
- Monosomy 7: Negative.
- NPM1 mutation, nos: Negative.
- RUNX1–RUNX1T1 fusion: Positive.
- Test: Negative.
- Test: Negative; Chromosomal translocation: t(10;11)(p11.2;q23).
- Test: Negative; Chromosomal translocation: t(11;19)(q23;p13.1).
- Test: Negative; Chromosomal translocation: t(3;5)(q25;q34).
- Test: Negative; Chromosomal translocation: t(6;11)(q27;q23).
- Test: Negative; Chromosomal translocation: t(6;9).
- Test: Negative; Chromosomal translocation: t(9;11)(p22;q23).
- Test: Negative; Chromosome arm: q.
- Test: Positive; Chromosomal translocation: t(8;21).
- Trisomy 21: Negative.
- Trisomy 8: Negative.
- WT1 mutation, nos: Negative.
- Day 0: Leukocytes 59.3 ×10³/µL; Blast Count 73%.
- Minimal Residual Disease (Flow Cytometry): Negative.

Biospecimens (2 samples)
- Sample TARGET-20-PARZHT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-20-PARZHT-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_AML_ClinicalData_LowDepthRNAseq_20230720.xlsx (sheet Clinical Data):
- First Event: Censored
- Overall Survival Time in Days: 2584
- WBC at Diagnosis: 59.3
- Peripheral blasts (%): 73
- CNS disease: No
- Chloroma: No
- FAB Category: M2
- t(6;9): No
- t(8;21): Yes
- t(3;5)(q25;q34): No
- t(6;11)(q27;q23): No
- t(9;11)(p22;q23): No
- t(10;11)(p11.2;q23): No
- t(11:19)(q23:p13.1): No
- inv(16): No
- del5q: No
- del7q: No
- del9q: No
- monosomy 5: No
- monosomy 7: No
- trisomy 8: No
- trisomy 21: No
- MLL: No
- Minus Y: No
- Minus X: No
- Cytogenetic Complexity: 1
- ISCN: 46,XX,t(8;21)(q22;q22)[20]
- FLT3/ITD positive?: No
- FLT3 PM: Yes
- NPM mutation: No
- CEBPA mutation: No
- WT1 mutation: No
- c-Kit Mutation Exon 8: No
- c-Kit Mutation Exon 17: No
- MRD at end of course 2: No
- MRD % at end of course 2: 0
- CR status at end of course 1: CR
- CR status at end of course 2: CR
- Risk group: Low Risk
- SCT in 1st CR: No
- Blast count used for RNA seq: 73
- Gene Fusion: RUNX1-RUNX1T1

Additional fields from the TARGET clinical supplement workbook TARGET_AML_ClinicalData_Validation_20230720.xlsx (sheet Clinical Data):
- Event Free Survival Time in Days: 2200
- Overall Survival Time in Days: 2200
- FLT3 PM: No
- Gemtuzumab ozogamicin treatment: Gentuzumab ozogamicin treatment
